Gene-level copy-number profile of tumor specimen TCGA-QR-A6GZ-05A from TCGA case TCGA-QR-A6GZ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 31.7 years (11,573 days).
Specimen TCGA-QR-A6GZ-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.f94012ec-9b94-438e-a30f-e896d3024a31.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QR-A6GZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate.
https://portal.gdc.cancer.gov/files/f5326a9c-2c65-4be6-9eae-01be1f520e78

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 8,962; copy number 2: 47,829; copy number 3: 3,349; copy number 5: 116.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:71,794,232–71,837,012, 1 gene (within-gene range 0–2): NEGR1-IT1.
- chr2:195,003,711–195,026,370, 1 gene: AC010983.1.
- chr3:18,954,943–18,955,049, 1 gene: RNU6-138P.
- chr3:105,366,909–105,576,900, 1 gene (within-gene range 0–1): ALCAM.
- chr3:110,527,482–110,551,965, 2 genes: AC117430.1, RNU6ATAC15P.
- chr5:89,900,664–89,990,883, 1 gene (within-gene range 0–2): AC113167.1.
- chr5:114,576,041–114,579,970, 1 gene: LINC01957.
- chr5:125,966,777–125,968,085, 1 gene: RPSAP37.
- chr5:155,491,336–155,493,598, 1 gene: AC008725.1.
- chr11:81,552,226–81,556,425, 2 genes: MTND4LP18, MTND6P25.
- chr21:18,614,431–18,650,360, 1 gene (within-gene range 0–3): AF240627.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 116 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,764,503–106,443,583, 116 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,576. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
